CCDI case PBCDLB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c6c3ccf8-648e-4dbc-aac8-23728803b38f

Demographics
Sex at birth: female.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.4 years (1,971 days).

Biospecimens (3 samples)
- Sample 0DPE96: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPE9F: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPEA1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
